Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7406, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7406-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

(A) LEFT NECK #1:

Mandibular gland with fibrosis and inflammation, no tumor.

Two lymph nodes, no tumor.

(B) COMPOSITE RESECTION LEFT MANDIBLE AND BASE OF TONGUE

POORLY DIFFERENTIATED KERATINIZING SQUAMOUS CARCINOMA OF TONGUE,
THICKNESS 1.5 CM WITH LYMPHATIC AND VASCULAR INVASION.

Margins of lesion free of tumor.

(C) BASE OF TONGUE MARGIN:

Squamous mucosa, no tumor present.

(D) ANTERIOR MARGIN:

MICROSCOPIC FOCUS OF ATYPICAL EPITHELIAL CELLS SUGGESTIVE OF SQUAMOUS
CARCINOMA.

(E) MEDIAL PHARYNGEAL WALL:

Squamous mucosa, no tumor.

(F) SUPERIOR MARGIN:

Fibroconnective tissue and skeletal muscle, no tumor present.

(G) NEW ANTERIOR MARGIN:

Squamous mucosa, no tumor present.

GROSS DESCRIPTION

(A) LEFT NECK #1 - Salivary gland with attached adipose tissue, 4.0 x 2.8 x 1.0 cm. Within the surrounding adipose tissue, two possible lymph nodes are identified that are 0.3 and 0.6 cm in greatest dimension.

SECTION CODE: A1, cross-section of salivary gland; A2, two possible lymph nodes.

(B) COMPOSITE RESECTION LEFT MANDIBLE AND BASE OF TONGUE - Consists of a portion of left mandible, 7.0 x 5.5 x 1.6 cm, and a separate portion of base of tongue (3.5 x 2.8 x 3.3 cm).

An ulcerated tumor, 1.5 x 1.0 x 0.5 cm, is present in the posterior portion of the base of tongue corresponding to the left tonsillar area. The tumor is present within 0.2 cm from the posterior lateral margin of the specimen (not the true margin), 0.7 cm from the anterior/inferior margin, 0.8 cm from the lateral margin and 1.2 cm from the medial margin. The tumor comes within approximately 1.0 mm of the deep margin which appears to be free.

INKING CODE: Black-deep margin; red-medial margin; yellow-lateral margin; blue-superior margin; green-inferior margin.

SECTION CODE: B1, tumor-superior margin, perpendicular section; B2, tumor-lateral margin; B3, tumor-inferior margin; B4, medial margin, en face;

[page 2 of 2]
Case type: Surgical History

B5-B9, full thickness section of tumor including deep margin. [REDACTED]
(C) BOT MARGIN - A single portion of tan-pink soft tissue (1.1 x 0.5 x 0.3 cm), entirely submitted in C. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

(D) ANTERIOR MARGIN - A sliver of tan-pink tissue (2.0 x 0.2 x 0.2 cm), entirely submitted in D. [REDACTED]
*FS/DX: FOCUS OF ATYPICAL CELLS CONSISTENT WITH SQUAMOUS CELL

CARCINOMA. [REDACTED]

(E) MEDIAL PHARYNGEAL WALL - A single sliver of tan-pink mucosa (1.5 x 0.2 x 0.2 cm). Entirely submitted in E. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

(F) SUPERIOR MARGIN - A single portion of tan-pink soft tissue (1.0 x 0.3 x 0.3 cm). Inked at one edge. Entirely submitted for frozen section in F. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

(G) NEW ANTERIOR MARGIN INKED TRUE MARGIN - A strip of mucosa, 2.5 cm. One margin of the specimen is inked blue indicating the true margin. The entire specimen is submitted in G. [REDACTED]
*FS/DX: NO TUMOR PRESENT. [REDACTED]

SNOMED CODES

M-80703 T-53000

Source: NCI Genomic Data Commons file b5310dbc-673d-430b-b00e-e02c78ee13a6 (TCGA-CV-7406.0944A203-7DBC-4B27-B9C8-007E79DA3F02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).